Somatic mutation profile of tumor specimen 0DWTBR from CCDI case PBCNCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.1 years (1,483 days).
Specimen 0DWTBR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 662a2237-e44e-4e07-990c-56112fd88c18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWTA7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3385da91-a665-4d66-b6b2-684330fdb24e

The open-access MAF lists 44 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Intron 3, 3'UTR 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP6 | c.5441G>A p.R1814K | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55232388; called by muse, mutect2
- AL136295.3 | c.523del p.G175Afs*15 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | catalogued as rs760463204; called by mutect2, varscan2
- BCLAF3 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs752688024; called by mutect2, varscan2
- EXTL1 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs750852433, COSV65337520; called by muse, mutect2, varscan2
- ITGAL | c.2728G>T p.D910Y | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63324221; called by muse, mutect2, varscan2
- MAGEC1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs774360885, COSV53577524; called by muse, varscan2
- PCDHGA6 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs750510871; called by muse, mutect2, varscan2
- PNLIPRP2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 25/493 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554868907, COSV53943198; called by muse, mutect2
- TMC8 | c.2083G>A p.V695I | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs752088229; called by muse, mutect2, varscan2
- TVP23A | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 126/339 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51596263; called by muse, mutect2, varscan2
- UNC5CL | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs139549480; called by muse, mutect2, varscan2
- WDR49 | c.138G>A p.W46* (on ENST00000308378 / NM_001366158.1; = p.W387* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 80/241 reads (33%) | catalogued as rs1431166293; called by muse, mutect2, varscan2
- ZMYND19 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53812186; called by mutect2, varscan2
- ANAPC7 | c.1065C>G p.Y355* | Nonsense Mutation (SNP) | VAF 76/333 reads (23%) | called by muse, mutect2, varscan2
- ATR | c.6174G>A p.M2058I | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CDC42BPB | c.2470T>A p.W824R | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- CDHR2 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 133/452 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DAB2IP | c.2086G>T p.D696Y (on ENST00000408936; = p.D668Y on NM_032552.3) | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX3X | c.1781G>A p.G594E (on ENST00000399959; = p.G595E on NM_001356.5) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- EEF1G | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EFCAB5 | c.2314T>G p.F772V | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.033); called by muse, varscan2
- MLXIPL | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 195/362 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NEB | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 144/162 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, varscan2
- SH3RF2 | c.959T>A p.M320K | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.74328G>T p.E24776D (on ENST00000591111; = p.E17352D on NM_003319.4) | Missense Mutation (SNP) | VAF 134/338 reads (40%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- USP54 | c.1394G>C p.G465A | Missense Mutation (SNP) | VAF 129/338 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- VSTM1 | c.476G>C p.C159S | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ACAD11 | c.1602C>A p.G534= | Silent (SNP) | VAF 21/382 reads (5%) | called by muse, mutect2
- BTBD8 | c.2334T>C p.S778= (on ENST00000636805 / NM_001376131.1; = p.S265= on NM_015237.4) | Silent (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- CPHXL | c.1146C>T p.P382= | Silent (SNP) | VAF 72/368 reads (20%) | called by muse, mutect2
- CSPG4 | c.4254C>T p.S1418= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs773068876; called by muse, mutect2, varscan2
- FKBP8 | c.1095G>C p.R365= (on ENST00000222308 / NM_001308373.2; = p.R366= on NM_012181.5) | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- SPATA31D4 | c.2541G>T p.V847= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- TRAPPC6B | c.477G>A p.*159= (on ENST00000330149 / NM_001079537.2; = p.*131= on NM_177452.4) | Silent (SNP) | VAF 56/269 reads (21%) | called by muse, mutect2, varscan2
- TTC26 | c.1308G>C p.R436= | Silent (SNP) | VAF 18/624 reads (3%) | called by muse, mutect2
- VIT | c.855G>A p.L285= (on ENST00000389975 / NM_001177969.1; = p.L300= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as rs1168699393, COSV101007333; called by muse, mutect2, varscan2
- CLCA4 | c.1467+76G>T | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- DPP9 | c.2245-254G>T | Intron (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- DUSP11 | c.-19T>A | 5'UTR (SNP) | VAF 57/96 reads (59%) | called by muse, mutect2, varscan2
- ELK3 | c.1003-4228G>A | Intron (SNP) | VAF 185/328 reads (56%) | called by muse, mutect2, varscan2
- MSRA | c.*20C>G | 3'UTR (SNP) | VAF 60/151 reads (40%) | called by muse, mutect2, varscan2
- NAA30 | c.*56T>A | 3'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, varscan2
- SGK1 | c.-51C>T | 5'UTR (SNP) | VAF 16/49 reads (33%) | catalogued as rs760040042; called by muse, mutect2, varscan2
- ZNF491 | c.*60G>C | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
